Gene-level copy-number profile of specimen HCM-CSHL-0384-D37-85P from HCMI case HCM-CSHL-0384-D37, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubulovillous adenoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage 0; Tumor grade: GX; Age at diagnosis: 51.4 years (18,759 days).
Specimen HCM-CSHL-0384-D37-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dcdb9419-970f-4905-9ef4-d3edf6219ef0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0384-D37-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/25c7495d-0f57-4fd8-a11e-8fb0799ffaa2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,850; copy number 2: 54,867; copy number 3: 199.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 994. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
